Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A25G, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A25G-01A (Primary Tumor).

[page 1 of 2]
	Yes	No
mPAX Discrepancy		

FINAL DIAGNOSIS -----

1. TOTAL THYROID (THYROIDECTOMY):

SPECIMEN TYPE: Total thyroidectomy.

TUMOR SITE: Left lobe.

HISTOLOGIC TYPE:

Papillary carcinoma, tall cell variant.

TUMOR SIZE: Greatest dimension 4.0 cm

FOCALITY: Unifocal

LYMPH NODES:

One (1) lymph node is negative for tumor.

EXTENT OF INVASION

PRIMARY TUMOR:

pT3: Tumor > 4 cm, with minimal extrathyroidal extension.

REGIONAL LYMPH NODES:

pNO: No regional lymph node metastasis.

DISTANT METASTASIS:

pMx: Cannot be assessed.

MARGINS:

Involved by invasive carcinoma, left superior posterior

VENOUS/LYMPHATIC INVASION:

Present

ADDITIONAL PATHOLOGIC FINDINGS:

Nodular hyperplasia.

NOTE: This case was reviewed at our

ICD-0-3

carcinoma, papillary, Tall cell 8344/3

Site: thyroid, nos C73.9

hw
5/4/11

[page 2 of 2]
GROSS DESCRIPTION

PART #1: TOTAL THYROID

Dictated

The specimen is received fresh labeled xxxx and designated "Total thyroid." The specimen is oriented with stitch marking the left thyroid tumor. The specimen weighs 37.93 grams. The left lobe measures approximately 6.5 x 4 x 1.9 cm, and the right measures 4.5 x 2 x 0.6 cm. Orange ink is placed on the anterior surface of the thyroid and black ink is placed on the posterior. The specimen is then serially sectioned to reveal a tumor measuring 4 x 3 x 2.7 cm in the left superior pole of the thyroid. The cut surface of the tumor is soft, pale tan in color and notable for a multicystic papillary appearance. A portion of the tumor is harvested for potential future studies. The tumor very closely approaches the inked margin on both the anterior and posterior surfaces of the thyroid. The remainder of the thyroid does not reveal any suspicious lesions or masses. The parenchyma is beefy red. The tumor is submitted along with representative sections of left inferior lobe and right.

SUMMARY OF SECTIONS

9 - A-I - 1 TO 2 EACH (EACH DESIGNATED TUMOR)

1 - J - 2 (LEFT INFERIOR)

1 - K - 2 (RIGHT UPPER)

1 - L - 2 (RIGHT LOWER)

12 - TOTAL - M

Source: NCI Genomic Data Commons file a669d48b-f41b-4846-b0f2-8c15746df7ba (TCGA-ET-A25G.DC56DF43-2D17-490A-AE01-5C007031C3C8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).